Gene-level copy-number profile of tumor specimen TCGA-DK-AA76-01A from TCGA case TCGA-DK-AA76, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 64.5 years (23,542 days).
Specimen TCGA-DK-AA76-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.66b94e6b-91da-4dee-b93a-ca860ad00069.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-AA76-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d0cf67d4-1916-4a66-8a89-2fe01959e1f0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 776; copy number 2: 8,023; copy number 3: 19,595; copy number 4: 27,223; copy number 5: 1,133; copy number 6: 2,831; copy number 7: 78; copy number 8: 57; copy number 9: 16; copy number 10: 5; copy number 15: 11; copy number 20: 20; copy number 25: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-AA76-01A-11D-A390-01): tumor purity 0.93, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,581,357–213,021,545, 7 genes (within-gene range 0–2): AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2.
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr14:43,300,263–43,541,826, 3 genes: HNRNPUP1, AL583809.1, KRT8P2.
- chr14:51,454,512–51,730,727, 4 genes (within-gene range 0–2): FRMD6-AS2, FRMD6, RNU6-1291P, AL122125.1.
- chr14:67,819,779–68,730,218, 7 genes (within-gene range 0–2): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6.
- chr16:3,611,728–3,880,713, 6 genes: DNASE1, AC006111.2, TRAP1, AC006111.3, CREBBP, AC007151.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 60 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:177,019,340–177,228,000, 1 gene, copy number 9 (within-gene range 6–9): TBL1XR1.
- chr3:177,120,691–177,767,379, 9 genes, copy number 9 (within-gene range 3–9): Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1.
- chr6:6,346,465–6,622,771, 1 gene, copy number 10 (within-gene range 7–15): LY86-AS1.
- chr6:6,450,356–7,881,728, 33 genes, copy number 10–20 (within-gene range 6–20): AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6.
- chr6:9,124,221–10,211,608, 2 genes, copy number 25 (within-gene range 3–25): AL137220.1, OFCC1.
- chr6:21,485,896–22,654,455, 12 genes, copy number 9–25 (within-gene range 6–25): LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1.
- chr8:76,162,119–76,308,315, 2 genes, copy number 10 (within-gene range 3–10): AC011029.1, RNU2-54P.

Autosomal genes at a single copy (total copy number 1): 771. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
